Surgical pathology report (de-identified scan), TCGA case TCGA-49-AAR9, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-AAR9-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

* AMENDED *

=====

INTERPRETATION AND DIAGNOSIS:

1. SOFT TISSUE, "R4" (BX): ONE (1) BENIGN LYMPH NODE.
2. RIGHT LUNG (PNEUMONECTOMY):
- INFILTRATING POORLY DIFFERENTIATED ADENOCARCINOMA OF THE LUNG INVADING THROUGH THE PLEURA AND INTO BONE AND SOFT TISSUES OF THE CHEST WALL (7.5 CM).
- THE TUMOR EXTENDS TO WITHIN 1 MM OF THE FASCIAL RESECTION PLANE. THE BRONCHIAL MARGIN IS NEGATIVE FOR TUMOR. THE CHEST WALL SOFT TISSUE MARGINS ARE NEGATIVE FOR TUMOR.
- FIVE (5) PERIBRONCHIAL LYMPH NODES ARE NEGATIVE FOR METASTATIC CARCINOMA. THESE LYMPH NODES DEMONSTRATE SCATTERED HYALINIZED GRANULOMAS.
- THE PATHOLOGIC STAGE IS T3 N0 MX.
3. SOFT TISSUE, "R10" (BX): ONE (1) BENIGN LYMPH NODE WITH SCATTERED HYALINIZED GRANULOMAS.
4. SOFT TISSUE, "R11" (BX): ONE (1) BENIGN LYMPH NODE.
5. SOFT TISSUE, "STATION 7" (BX): ONE (1) BENIGN LYMPH NODE WITH SCATTERED HYALINIZED GRANULOMAS.

NOTE: This cae was amended to clarify the status of the margins. The diagnosis did not change.

*Electronic signature

=====

GROSS DESCRIPTION

(Continued on next page.)

ICD O-3

Adenocarcinoma NOS 8140/3
Site R Lung NOS C34.9
JY 5/20/14

[page 2 of 4]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
pg. 2

=====

PART #1: FS: R4
Resident Pathologist:

FROZEN SECTION DIAGNOSIS --
FS: R4: NEGATIVE FOR TUMOR.

The specimen is received fresh labeled [REDACTED] and is designated as R4. It consists of multiple pieces of tan black soft tissue, measuring 0.9 x 0.8 x 0.7 cm. Entirely submitted for frozen section.

SUMMARY OF SECTIONS

- 1 - FSC - M
- 1 - TOTAL - M

PART #2: RIGHT LUNG
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and is designated as right lung. It consists of a 740 gram right lung, measuring 23 x 21 x 0.8 cm. Attached to the right upper lobe is a segment of chest wall, including four ribs, each measuring 11 cm in length. A large mass is present in the right upper lobe centered in the anterior, peripheral portion of the lobe and extending through the middle two ribs, obliterating the ribs. Tumor extends to the inked superior anterior chest wall margin. Tumor measures 7.5 x 6 x 4.5 cm and is fleshy, white tan with no large regions of necrosis. Tumor extends from the peripherally-located mass centrally towards the hilum, surrounds a more central branch of the pulmonary artery and may invade a periarterial 0.6 cm lymph node by direct extension. No vascular invasion is noted. Dissection of the hilar bronchi reveals no grossly apparent bronchial invasion. Tumor surrounding vessel and extending into one node with two adjacent nodes bisected is submitted in cassettes G and H. Tumor extending into lung is submitted in cassette I. Uninvolved lower lobe is in cassette J. Palpation and sectioning of the uninvolved lobes reveals alveolated lung parenchyma without masses or lesions suspicious for carcinoma.

SUMMARY OF SECTIONS

- 1 - A - 2 (BRONCHIAL MARGIN)
- 1 - B - 1 (VASCULAR MARGIN)

(Continued on next page.)

[page 3 of 4]
=====

- 1 - C - 1 (HALF OF ONE HILAR NODE)
- 1 - D - 1 (HALF OF ONE HILAR NODE)
- 1 - E - 1 (TUMOR)
- 1 - F - 2 (TUMOR EXTENDING TO INKED ANTERIOR CHEST WALL MARGIN)
- 2 - G,H - 1 EACH (3 LYMPH NODES, BISECTED)
- 1 - I - 1 (TUMOR)
- 1 - J - 1
- 5 - -5 - M EACH
- 15 - TOTAL - M

PART #3: R 10
Resident Pathologist:

The specimen is received fresh, labeled with the patient's name [REDACTED] and designated R10. It consists of one piece of black/red tissue measuring 2 x 1.5 x 0.5 cm. The specimen is bisected. One half is submitted to [REDACTED], the remainder is submitted in cassette A.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

PART #4: R11
Resident Pathologist:

The specimen is received fresh, labeled with the patient's name [REDACTED] and designated R11. It consists of one piece of black/red/tan tissue measuring 1.3 x 1.0 x 0.5 cm. It is bisected and one half is submitted to [REDACTED] lab.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

(Continued on next page.)

[page 4 of 4]
PART #5: STATION 7
Resident Pathologist:

The specimen is received fresh, labeled with the patient's name [REDACTED] and designated station 7. It consists of one wedge shaped piece of black/tan tissue measuring 2.5 x 1.5 x 0.5 cm. It is bisected and one half is submitted to [REDACTED]. The remainder is submitted in cassette A.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Source: NCI Genomic Data Commons file 2ee422d9-8fbd-4339-b640-b51ca6fc4b4a (TCGA-49-AAR9.F2AB65ED-823F-446C-92CB-5F9DAB58D37A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).